Somatic mutation profile of tumor specimen 0DRPJ1 from CCDI case PBCGNH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.4 years (5,626 days).
Specimen 0DRPJ1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53da154b-02fd-4574-bcde-f2dbe972ef48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRPJ8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ed65533-162c-4ef7-9fe0-c2aa2b11ffaf

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PAF1 | c.505_508del p.Y169Kfs*52 | Frame Shift Del (DEL) | VAF 37/319 reads (12%) | called by mutect2, pindel, varscan2
- USP9X | c.5441A>G p.D1814G | Missense Mutation (SNP) | VAF 28/656 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HCN1 | c.2115C>T p.S705= | Silent (SNP) | VAF 12/346 reads (3%) | catalogued as COSV57529414; called by muse, mutect2
